Gene-level copy-number profile of tumor specimen HCM-SANG-1333-C20-01A-01D-A80T-32 from HCMI case HCM-SANG-1333-C20, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Rectum, NOS; Tumor grade: G2.
Specimen HCM-SANG-1333-C20-01A-01D-A80T-32: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 8a134db1-41e3-4808-b1d3-f530dc0805af.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-SANG-1333-C20-10A-01D-A80T-32 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,707 have no estimate.
https://portal.gdc.cancer.gov/files/f160789b-737f-4a7b-bbb4-447cf3f3c45b

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 13; copy number 1: 1,129; copy number 2: 45,397; copy number 3: 9,674; copy number 4: 2,698; copy number 5: 2; copy number 7: 3.

Homozygous deletions (total copy number 0; autosomes only): 13 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:89,078,010–89,100,361, 3 genes (within-gene range 0–2): IGKV2-14, IGKV3-15, IGKV1-16.
- chr5:135,802,985–135,827,546, 2 genes: MIR5692C1, AC114296.1.
- chr16:10,718,633–10,725,296, 8 genes: MTCYBP33, MTND6P33, MTND5P33, MTND4P34, MTND4LP24, MTND3P13, MTCO3P24, MTATP6P24.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 5 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:34,049,966–34,096,225, 2 genes, copy number 5 (within-gene range 3–5): RN7SKP114, AL354989.1.
- chr10:38,783,004–38,783,108, 1 gene, copy number 7: AL590623.1.
- chr21:10,640,028–10,649,835, 2 genes, copy number 7: AF254982.1, IGHV1OR21-1.

Autosomal genes at a single copy (total copy number 1): 617. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
